Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RL-01A (Primary Tumor).

[page 1 of 3]
Patient:

Page 1 of 3

1CD-0-3

Report for

adenocarcinoma, endocervical type 8384/3

Site: cervix, NOS C53.9 9/8/11

TEST: SURG PATH FINAL REPORT
Collected Date & Time:

Result Name
Surg Path Final

Results
Patient Name:

Units

Reference Range

Patient Name:
Accession No.

A P - Surg Path Final Report
Accession Number Collected Received Pathologist
Date/Time Date/Time
1

Diagnosis:

1) UTERUS, TUBES AND OVARIES, RADICAL HYSTERECTOMY
CERVIX

ENDOCERVICAL ADENOCARCINOMA ARISING NEAR THE
ENDOCERVICAL/CERVICAL JUNCTION (2.5cm)

TUMOR INVADERS TO APPROXIMATELY 4 MM IN DEPTH

INKED VAGINAL CUFF MARGINS ARE FREE OF TUMOR

NO VASCULAR SPACE INVASION IDENTIFIED (SEE PROTOCOL)

pt1b1p1p1mx

TOTAL OF 1 OUT OF 33 LYMPH NODES POSITIVE FOR METASTATIC
CARCINOMA (1/33) - SINGLE RIGHT PELVIC LYMPH NODE INVOLVED.

ENDOMETRIUM

LATE SECRETORY PHASE ENDOMETRIUM

NO EVIDENCE OF ATYPIA OR CARCINOMA

MYOMETRIUM

SUPERFICIAL ADENOMYOSIS

BILATERAL OVARIES AND TUBES

RIGHT OVARY

CYSTIC OVARY

ACUTE AND CHRONIC SALPINGITIS RIGHT FALLOPIAN TUBE

LEFT OVARY

MULTICYSTIC OVARY

FALLOPIAN TUBE WITH NO SIGNIFICANT LESION

2) RIGHT PERIAORTIC NODES

THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3)

3) RIGHT PELVIC LYMPH NODES

ONE OUT OF SEVENTEEN LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA
(1/17)

4) LEFT PERIAORTIC LYMPH NODES

FOUR LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/4)

5) LEFT PELVIC LYMPH NODES

NINE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/9)

(Electronically signed by)

Verified:

TAP Protocol:

Patient Name:

Accession No.:

A P - Surg Path Final Report
Accession Number Collected Received Pathologist
Date/Time Date/Time

[page 2 of 3]
Patient:

Page 2 of 3

1: Cervix, Macroscopic
SPECIMEN TYPE:
Radical Hysterectomy
TUMOR SITE:
Not specified
TUMOR SIZE:
Greatest dimension: 2.5 cm
OTHER ORGANS PRESENT:
Right ovary
Left ovary
Right fallopian tube
Left fallopian tube
Uterine corpus
Vaginal cuff
1: Cervix, Microscopic
HISTOLOGIC TYPE:
*Mucinous, endocervical type
HISTOLOGIC GRADE:
G2: Moderately differentiated
PRIMARY TUMOR (pT) TNM (FIGO):
pT1b1 (IB1): Cervical carcinoma confined to uterus, clinically visible
lesion 4.0 cm or less in greatest dimension
REGIONAL LYMPH NODES (pN):
pN1: Regional lymph node metastasis
Number examined: 33
Number involved: 1
DISTANT METASTASIS (pM):
pMX: Cannot be assessed
MARGINS:
Margins uninvolved by invasive carcinoma
*VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):
*Absent
Specimen(s):
1. UTERUS, TUBES AND OVARIES
2. RIGHT PERIAORTIC NODES
3. RIGHT PELVIC NODES
4. LEFT PERIAORTIC NODES
5. LEFT PELVIC NODES
Clinical Information:
Cervical cancer
Patient Name:
Accession No.:
A P - Surg Path Final Report
Accession Number Collected Received Pathologist
Date/Time Date/Time

Frozen Section Diagnosis:
IFS: Endocervical adenocarcinoma

Gross Description:
1) Specimen received fresh, uterus, tubes and ovaries. It consists of a uterus, tubes and ovaries which weighs 320 grams. The uterus measures 12 x 10 x 4 cm. The right ovary measures 5.5 x 3.5 x 2.5, the right tube measures 5 x 1.5 x 0.5 cm. The left ovary measures 3.5 x 3 x 2.5 cm, the left tube measures 5.5 cm. The tumor appears to protrude through the external cervical os. The cervix measures 5.5 cm long x 4.5 x 4.5 cm. The vaginal cuff appears grossly free of tumor. The endometrium is thin and the cavity only measures 4 x 4. The myometrium measures approximately 2 cm and is fairly unremarkable. The tumor is located in

[page 3 of 3]
Patient:

Page 3 of 3

the

distal endocervical canal. The specimen is inked at the margins and opened

to reveal a polypoid endocervical mass measuring 2.5 x 2 x 1.5, fleshy and

gray/tan in color and protrudes out of the external os. Representative sections are submitted for frozen section in IFS. The specimen is submitted for Precision Therapeutics as well as studies with

. The specimen is placed back into formalin for later fixation. Representative sections are as follows:

1FSA: Frozen section -

-endocervix

1B: Anterior endometrium/myometrium

1C: Posterior endometrium/myometrium

1D: Additional endometrium/myometrium for study

1E-G: Vaginal cuff margin

1H: Cystic right ovary and tube

1I: Cystic left ovary and tube

1J - M: Endocervical mass, entirely submitted, anterior and posterior

1N: Additional tumor for study

1O: Additional tumor for additional studies

1P: Right parametrial tissue and vessels

1Q: Left parametrial tissue and vessels

2) Specimen 2, right periaortic nodes, consists of a fat pad measuring 1 x 1 x 1 cm. The possible nodes are submitted in cassettes 2A -

-B.

3) Specimen 3, right pelvic nodes, consists of a fat pad measuring approximately 6 x 6 x 2 cm. Possible lymph nodes are submitted in cassette 3A -

-F.

4) Specimen 4, left periaortic lymph nodes, consists of a fat pad measuring 1.5 x 1.5 x 1 cm. Entirely submitted in cassettes 4A -

-B.

Patient Name:

Accession No.:

A P - Surg Path Final Report			
Accession Number	Collected	Received	Pathologist
	Date/Time	Date/Time	

5) Specimen 5, left pelvic nodes, consists of a fat pad measuring approximately 6 x 5 x 1 cm. Possible lymph nodes are dissected and submitted entirely in cassettes 5A -

-E.

Microscopic Description:

A microscopic exam was performed.

Source: NCI Genomic Data Commons file 6d3cc9b2-4f88-419b-a9c9-e1ea65179bd3 (TCGA-EK-A2RL.7AE4CF2E-602B-4860-8919-095EA5378504.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).